Surgical pathology report (de-identified scan), TCGA case TCGA-TQ-A7RP, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Sao Paulo, specimen TCGA-TQ-A7RP-01A (Primary Tumor).

ICD-O 3
Oligoastrocytoma, grade II
9382/3
Site Brain, supratentorial NOS
C71.0
D Brain, insula C71.0
JW 10/4/13

Nature of material: Brain

Received on:

Macroscopy:

Received in formalin, multiple whitish-brown, soft and irregular tissue fragments, measuring together 6.2 x 3.0 x 1.5 cm and weighing 13.0g.

Microscopy:

Histological sections stained with H & E demonstrate partial brain parenchymal infiltration by glial neoplasm composed of two cell populations of oligodendroglial and astrocytic phenotype. The oligodendroglial component is represented by round nuclei cells, delicate chromatin and inconspicuous nucleoli, with scant cytoplasm. Such cells infiltrate the adjacent neocortex, in the form of isolated cells, forming small aggregates around neurons (Neuronal satellitosis). In some areas, there is vacuolation of neuropil, with formation of microcysts, in basophil-rich and mucinous matrix. The astrocytic component, less obvious, is represented by cells of irregular nuclei, dense chromatin and eosinophilic cytoplasm, with imprecise limits, infiltrating predominantly white substance, which shows areas with refractive neuropil and occasional reactive astrocytes. Mitotic figures are rare in this material. It was not observed vessels with microvessel proliferation or areas of necrosis. It is evident, also, some fragments of neocortex free of involvement by neoplasia.

Diagnosis:

Surgical resection product of lesion in left insula region:

- Compatible with diffuse oligoastrocitoma, grade II in this sample (ICD-O 9382/3) - see notes.

NOTES:

1. In the sample sent for intraoperative analysis (oligoastrocitoma grade II), there is a predominance of astrocytic component.
2. It must be correlated with neuroimaging studies in order to evaluate the possibility of higher grade areas were not represented in the material sent for histology.
3. We included all the fragments sent for pathological examination.

PROFESSIONAL PARTICIPANTS OF REPORT

Source: NCI Genomic Data Commons file f21caac7-2200-46d0-b767-45cd2e503207 (TCGA-TQ-A7RP.27A97401-6DB1-4439-A06D-E0CC46BD5CC0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).